Gene-level copy-number profile of tumor specimen ALCH-B0AE-TTP1-B from ALCHEMIST case ALCH-B0AE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 61.0 years (22,270 days).
Specimen ALCH-B0AE-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d5997220-28d3-4097-b013-3051a88db96f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0AE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/d2de770d-78ae-4546-89fd-9edf3a3241e5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 540; copy number 1: 12,714; copy number 2: 40,185; copy number 3: 2,936; copy number 4: 499; copy number 5: 1,385; copy number 6: 396; copy number 7: 239; copy number 10: 10.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:904,834–921,016, 4 genes: AL645608.6, AL645608.2, AL645608.4, LINC02593.
- chr1:12,791,397–12,841,357, 4 genes: PRAMEF1, LINC01784, PRAMEF11, PRAMEF30P.
- chr1:12,857,086–12,861,909, 1 gene (within-gene range 0–1): PRAMEF2.
- chr2:231,037,523–231,049,719, 1 gene: C2orf72.
- chr3:10,566,255–10,570,375, 1 gene (within-gene range 0–1): ATP2B2-IT1.
- chr5:177,801,204–177,803,344, 1 gene: AC140125.1.
- chr8:12,676,035–12,697,273, 3 genes: AC068587.1, OR7E8P, OR7E15P.
- chr15:73,335,260–73,342,387, 1 gene (within-gene range 0–1): AC068397.2.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:22,090,743–22,413,744, 8 genes: UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000.
- chr21:13,038,160–13,067,033, 2 genes: ANKRD30BP2, RNU6-614P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,030 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:88,948,142–198,123,232, 1,763 genes, copy number 5–10 (broad region; genes not listed).
- chr6:41,905,354–44,527,448, 101 genes, copy number 7 (broad region; genes not listed).
- chr6:48,213,604–58,438,364, 154 genes, copy number 6–7 (broad region; genes not listed).
- chr7:37,032–37,477, 1 gene, copy number 6: AC215522.1.
- chr8:140,657,900–141,002,216, 4 genes, copy number 5: PTK2, MIR151A, AC105235.1, RNA5SP278.
- chr8:144,137,774–144,143,664, 2 genes, copy number 5: HGH1, TSSK5P.
- chr9:136,744,017–136,748,525, 2 genes, copy number 7 (within-gene range 2–7): LCN6, MIR6722.
- chr17:39,757,718–39,864,312, 3 genes, copy number 5: IKZF3, KRT8P34, AC090844.1.

Autosomal genes at a single copy (total copy number 1): 10,371. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
